CCDI case PBBRIE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of limbs.
https://portal.gdc.cancer.gov/cases/d0acb6f4-9a4d-4956-80de-e64dbba01084

Demographics
Sex at birth: female; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Pleomorphic liposarcoma: ICD-O-3 morphology code: 8854/3; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 16.2 years (5,904 days).

Biospecimens (2 samples)
- Sample 0DFJJ4: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DFJKT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
